Somatic mutation profile of tumor specimen MMRF_2266_1_BM_CD138pos (aliquot MMRF_2266_1_BM_CD138pos_T1_KHS5U_L09502) from MMRF case MMRF_2266, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.7 years (26,909 days).
Specimen MMRF_2266_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d59e8736-cd87-4ed1-bb8a-bad74e9f9206.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2266_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2266_1_PB_Whole_C2_KHS5U_L09501; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2b76889-8b62-463b-bbc4-c527509462d4

The open-access MAF lists 183 somatic variants for this specimen: 83 protein-altering or splice-affecting, 22 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, 3'UTR 47, Silent 22, Intron 21, Nonsense Mutation 5, RNA 4, Splice Site 4, Frame Shift Del 3, 5'UTR 3, Frame Shift Ins 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.2537A>T p.D846V | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs779466403; ClinVar: likely pathogenic; called by mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC093246.1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | catalogued as rs984975545, COSV51125252; called by muse, mutect2
- ADCY6 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs762225071, COSV57169840; called by muse, mutect2, varscan2
- ANXA1 | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 104/166 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs868551604; called by muse, mutect2, varscan2
- ATP8B2 | c.587T>C p.I196T (on ENST00000672630; = p.I163T on NM_001005855.2) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1333673684; called by mutect2, varscan2
- BAZ1A | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62408933; called by muse, mutect2, varscan2
- C9orf153 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs777641427; called by muse, mutect2, varscan2
- CACNA1C | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as rs765581751, COSV59712057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMKV | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); catalogued as rs1245564647; called by muse, mutect2, varscan2
- CIBAR2 | c.739T>A p.S247T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV73320598; called by muse, mutect2, varscan2
- CSMD2 | c.8297C>A p.T2766N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.978); catalogued as COSV99586211; called by muse, mutect2, varscan2
- CUBN | c.9349C>T p.R3117C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs375906166, COSV64729645; called by muse, mutect2, varscan2
- DCAF11 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs373070338; called by muse, mutect2, varscan2
- DCHS1 | c.6106C>T p.L2036F | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs74961719; called by muse, mutect2, varscan2
- DNAH17 | c.6110G>A p.G2037D | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.79); catalogued as rs867305962; called by muse, mutect2, varscan2
- DSG4 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781483894; called by muse, mutect2, varscan2
- EIF2B5 | c.1226G>A p.R409Q (on ENST00000647909; = p.R401Q on NM_003907.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs139479760, COSV56603536; called by muse, mutect2, varscan2
- FBXO10 | c.2782C>A p.Q928K | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV52832944; called by muse, mutect2, varscan2
- FOXP2 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.988); catalogued as COSV63484215; called by muse, mutect2
- GZMB | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs1272502014; called by muse, mutect2
- HYDIN | c.11242C>T p.R3748C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs12102644, COSV66638865; called by muse, mutect2, varscan2
- LRP1B | c.3371A>G p.D1124G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285275028, COSV101260847; called by muse, mutect2, varscan2
- LRRC17 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 24/218 reads (11%) | catalogued as COSV99978550; called by muse, mutect2, varscan2
- PCDHGB4 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53930479, COSV53943562; called by muse, varscan2
- PITRM1 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56536949; called by muse, mutect2, varscan2
- PPFIA2 | c.1381C>A p.H461N | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100331848; called by muse, mutect2, varscan2
- PTPRS | c.3537G>A p.M1179I | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1461228258; called by muse, mutect2
- RAD51 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1468791932; called by muse, mutect2
- RHBDF2 | c.1730G>A p.C577Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51684292; called by muse, mutect2, varscan2
- SERPINA3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 68/69 reads (99%) | SIFT tolerated (0.95); PolyPhen benign (0.066); catalogued as rs1322682302, COSV67586351; called by muse, mutect2, varscan2
- SLC9A2 | c.1423C>A p.L475M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV52132002; called by muse, mutect2, varscan2
- WDFY4 | c.2744A>G p.Q915R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1051227768; called by muse, mutect2, varscan2
- ANKRD12 | c.5924C>T p.T1975I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2
- ARHGAP21 | c.5595dup p.S1866* | Frame Shift Ins (INS) | VAF 77/179 reads (43%) | called by mutect2, pindel, varscan2
- ATM | c.7954C>T p.P2652S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- C11orf86 | c.119A>C p.Q40P | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELSR3 | c.7785G>T p.R2595S | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CLCNKB | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- DCHS2 | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCK | c.297T>A p.Y99* | Nonsense Mutation (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- DENND10 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DNAH12 | c.5734A>G p.K1912E (on ENST00000351747; = p.K1931E on NM_001366028.2) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DROSHA | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- EOMES | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, varscan2
- ERP44 | c.588-24_591del p.X196_splice | Splice Site (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- F11 | c.1292A>G p.H431R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FADS3 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- FAT3 | c.1839C>G p.Y613* | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- FAT4 | c.6326C>A p.T2109N | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- IBTK | c.775C>A p.H259N | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KALRN | c.3848+1G>T p.X1283_splice | Splice Site (SNP) | VAF 23/34 reads (68%) | called by muse, mutect2, varscan2
- KIAA1109 | c.2864G>T p.R955I | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.276); called by muse, varscan2
- KIF26B | c.5768_5771dup p.V1925Lfs*65 | Frame Shift Ins (INS) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- LGR4 | c.2542T>G p.Y848D | Missense Mutation (SNP) | VAF 93/184 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MROH2B | c.2807C>A p.A936D | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- MRPS22 | c.469T>A p.F157I (on ENST00000310776 / NM_001363893.1; = p.F158I on NM_020191.4) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPS9 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTA3 | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MYH4 | c.3141A>T p.K1047N | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYH7B | c.929-1G>T p.X310_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- NRXN1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- OXTR | c.1098C>A p.S366R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PDGFRA | c.1882_1891+5del p.X628_splice | Splice Site (DEL) | VAF 34/157 reads (22%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.1724T>A p.L575H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PTPDC1 | c.98C>G p.P33R (on ENST00000375360 / NM_177995.3; = p.P85R on NM_152422.4) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAF1 | c.350A>C p.D117A | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- REXO1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 50/357 reads (14%) | called by muse, mutect2, varscan2
- ROCK2 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SBDS | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SEMA5A | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SHISA6 | c.436_443del p.Q146Gfs*69 | Frame Shift Del (DEL) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- SPTLC3 | c.133C>A p.H45N | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM5 | c.843C>A p.H281Q | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- STAT5B | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNPO2 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TANC2 | c.239del p.P80Lfs*4 | Frame Shift Del (DEL) | VAF 42/158 reads (27%) | called by mutect2, pindel, varscan2
- TENT5C | c.793del p.T265Lfs*2 | Frame Shift Del (DEL) | VAF 55/150 reads (37%) | called by mutect2, pindel, varscan2
- TGM7 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2
- TMEM41A | c.692T>G p.V231G | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- WFDC9 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX3 | c.5902C>A p.Q1968K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF318 | c.3526G>A p.E1176K | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BAHCC1 | c.4566G>T p.L1522= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- BSCL2 | c.300G>T p.L100= | Silent (SNP) | VAF 15/88 reads (17%) | called by muse, varscan2
- CARD6 | c.1455C>A p.I485= | Silent (SNP) | VAF 51/171 reads (30%) | catalogued as COSV54564823; called by muse, mutect2, varscan2
- CNTNAP3B | c.822C>T p.S274= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs751918387; called by muse, mutect2
- DHRS7 | c.141G>A p.E47= | Silent (SNP) | VAF 78/173 reads (45%) | catalogued as COSV53665902; called by muse, mutect2, varscan2
- DNAH5 | c.9513C>A p.T3171= | Silent (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- EGFLAM | c.1569A>G p.R523= | Silent (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2, varscan2
- FLAD1 | c.234A>C p.L78= | Silent (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- FLG2 | c.1884A>G p.S628= | Silent (SNP) | VAF 100/317 reads (32%) | called by muse, mutect2, varscan2
- KAT6B | c.5091C>T p.N1697= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as rs200958499, COSV99768184; called by muse, mutect2, varscan2
- LCT | c.3936G>A p.G1312= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs747030540; called by muse, mutect2, varscan2
- LRP2BP | c.711A>G p.A237= | Silent (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- MATN4 | c.1269G>A p.T423= (on ENST00000372754; = p.T382= on NM_003833.4) | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV100636958; called by muse, mutect2, varscan2
- MED23 | c.3837G>A p.L1279= | Silent (SNP) | VAF 30/31 reads (97%) | catalogued as rs1318028487; called by muse, mutect2, varscan2
- NID1 | c.3105C>A p.I1035= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- PHLDB1 | c.696G>A p.L232= | Silent (SNP) | VAF 104/207 reads (50%) | called by muse, mutect2, varscan2
- PHLPP1 | c.4212C>T p.T1404= | Silent (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- PLA2G7 | c.237C>T p.T79= | Silent (SNP) | VAF 27/156 reads (17%) | called by muse, mutect2, varscan2
- PPL | c.1905G>A p.L635= | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, varscan2
- RBM12 | c.2325A>T p.G775= | Silent (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- SLC14A1 | c.543C>T p.N181= | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, varscan2
- WIPF3 | c.87C>T p.P29= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs1206496646; called by muse, mutect2, varscan2
- ABI3 | c.*459C>A | 3'UTR (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- AC021218.1 | n.1387G>T | RNA (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
- ADIPOR1 | c.618-33del | Intron (DEL) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- AK6 | c.*239A>C | 3'UTR (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- ANKRD46 | c.*802del | 3'UTR (DEL) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- BACE1 | c.*1555G>C | 3'UTR (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- C4orf33 | c.-411_-388del | 5'UTR (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel
- CACNA1B | c.*1297G>A | 3'UTR (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- CAMK2A | c.*1952C>T | 3'UTR (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- CCNL1 | chr3:157160309 A>C | 5'Flank (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- CDC42BPA | c.599+114del | Intron (DEL) | VAF 7/47 reads (15%) | catalogued as rs113113284; called by pindel, varscan2
- CHMP3 | c.*1450C>A | 3'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, varscan2
- CNTNAP3P2 | n.821C>T | RNA (SNP) | VAF 6/81 reads (7%) | catalogued as rs1265328707; called by muse, mutect2
- CORO2B | c.*1177C>A | 3'UTR (SNP) | VAF 31/207 reads (15%) | called by muse, mutect2, varscan2
- CSF2RA | c.*334G>A | 3'UTR (SNP) | VAF 34/72 reads (47%) | catalogued as rs1468022166; called by muse, mutect2, varscan2
- CTSC | c.318+8646A>G | Intron (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- DCLK3 | c.*1738C>A | 3'UTR (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- DDOST | c.*551A>G | 3'UTR (SNP) | VAF 30/112 reads (27%) | called by muse, varscan2
- DPP9 | c.1429+122G>A | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, varscan2
- DPPA4 | c.*1428T>G | 3'UTR (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- DSEL | c.*4134G>A | 3'UTR (SNP) | VAF 16/75 reads (21%) | catalogued as rs1322311001; called by muse, mutect2, varscan2
- ELAPOR2 | c.*1380T>C | 3'UTR (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- ETV7 | c.*45C>A | 3'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- FAM43B | c.*291C>A | 3'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- GNL1 | c.*2815A>T | 3'UTR (SNP) | VAF 35/207 reads (17%) | called by muse, mutect2, varscan2
- HYDIN2 | n.9502G>C | RNA (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- KDM7A | c.*4048C>A | 3'UTR (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- LIN28A | c.*2111G>T | 3'UTR (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2
- LINC01547 | n.3999T>A | RNA (SNP) | VAF 86/178 reads (48%) | called by muse, mutect2
- LMAN2L | c.*132A>C | 3'UTR (SNP) | VAF 49/94 reads (52%) | called by muse, mutect2, varscan2
- LRRC15 | c.*1185A>T | 3'UTR (SNP) | VAF 88/200 reads (44%) | called by muse, mutect2, varscan2
- LRRTM1 | c.*136C>A | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- LTB | c.162+34G>A | Intron (SNP) | VAF 29/142 reads (20%) | catalogued as rs558646836, COSV53001046; called by muse, mutect2, varscan2
- LYST | c.4862+111A>T | Intron (SNP) | VAF 13/32 reads (41%) | called by mutect2, varscan2
- MECP2 | c.*2516C>T | 3'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- MIER3 | c.*1117G>T | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- MIP | c.*516_*564del | 3'UTR (DEL) | VAF 28/239 reads (12%) | called by mutect2, pindel
- MORC4 | c.*163C>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- MYLK2 | c.*826G>A | 3'UTR (SNP) | VAF 46/87 reads (53%) | called by muse, mutect2, varscan2
- MYOCD | chr17:12767750 TAAT>ATGTTTTAAATG | 3'Flank (INS) | VAF 10/53 reads (19%) | called by pindel, varscan2*
- NFYC | c.885+109T>C | Intron (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- NMD3 | c.-21+165C>T | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2
- NOL6 | c.*249G>T | 3'UTR (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- NRIP3 | c.*1099A>T | 3'UTR (SNP) | VAF 106/231 reads (46%) | called by muse, mutect2, varscan2
- NSD2 | c.1882-3916A>G | Intron (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2
- NT5C3A | c.*98_*104del | 3'UTR (DEL) | VAF 30/169 reads (18%) | called by pindel, varscan2
- PAQR5 | c.513-510T>C | Intron (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- PDZD4 | c.*95G>A | 3'UTR (SNP) | VAF 29/30 reads (97%) | called by muse, mutect2, varscan2
- PGM2L1 | c.*3255G>C | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, varscan2
- PHLDB2 | c.1720-1541C>G | Intron (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- PPIP5K1 | c.*506T>G | 3'UTR (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- PRLR | c.*2269A>G | 3'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as rs754598108; called by mutect2, varscan2
- PRR18 | c.*1338C>A | 3'UTR (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- PRR5L | c.*1880A>G | 3'UTR (SNP) | VAF 9/50 reads (18%) | catalogued as rs932489735; called by muse, varscan2
- PRRT2 | c.*395C>T | 3'UTR (SNP) | VAF 71/129 reads (55%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+310T>A | Intron (SNP) | VAF 63/182 reads (35%) | called by muse, varscan2
- PYGO1 | c.*2081A>T | 3'UTR (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- RHOBTB3 | c.228+283G>C | Intron (SNP) | VAF 11/114 reads (10%) | catalogued as rs1322691284; called by muse, mutect2, varscan2
- RNF144B | c.*2341_*2342insGT | 3'UTR (INS) | VAF 6/44 reads (14%) | catalogued as rs1002017572; called by pindel, varscan2
- RUFY1 | c.311-247A>G | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- SLC12A1 | c.1215+242_1215+243del | Intron (DEL) | VAF 14/130 reads (11%) | called by pindel, varscan2
- SLC1A2 | c.18-5097C>T | Intron (SNP) | VAF 18/46 reads (39%) | catalogued as rs1489993069; called by muse, mutect2, varscan2
- SLC30A4 | c.*5458A>G | 3'UTR (SNP) | VAF 17/124 reads (14%) | called by muse, varscan2
- SPATA48 | c.-134A>C | 5'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2
- TARS2 | c.387+187C>T | Intron (SNP) | VAF 83/171 reads (49%) | called by muse, mutect2, varscan2
- TIE1 | c.2218+49C>G | Intron (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- TMEM71 | c.*703C>A | 3'UTR (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- TP53I11 | c.-148+3760C>T | Intron (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- TSPAN9 | c.*3245del | 3'UTR (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- TTLL13P | c.1897-19C>G | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as rs1484766047; called by muse, mutect2
- TYK2 | c.*72T>G | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- U2SURP | c.*1061A>C | 3'UTR (SNP) | VAF 11/90 reads (12%) | catalogued as rs1240677218; called by muse, mutect2, varscan2
- UVSSA | chr4:1391919 T>A | 3'Flank (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2
- VEGFC | c.-113G>A | 5'UTR (SNP) | VAF 8/42 reads (19%) | catalogued as rs529352555; called by muse, mutect2, varscan2
- WWTR1 | c.*2554G>T | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- XBP1 | c.227+247T>C | Intron (SNP) | VAF 45/90 reads (50%) | catalogued as rs564354635; called by muse, mutect2, varscan2
- ZBED3 | c.*3465T>G | 3'UTR (SNP) | VAF 20/78 reads (26%) | called by mutect2, varscan2
- ZNF385D | c.*2224T>G | 3'UTR (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
